Somatic mutation profile of tumor specimen TCGA-AB-2901-03A (aliquot TCGA-AB-2901-03A-01W-0733-08) from TCGA case TCGA-AB-2901, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.5 years (10,046 days).
Specimen TCGA-AB-2901-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d547cf8c-eec0-4531-8e66-a0979d099860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2901-11A (Solid Tissue Normal), aliquot TCGA-AB-2901-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5623cc1a-7949-45af-88ab-00a62210f307

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SALL3 | c.2207G>T p.R736L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73306170; called by muse, mutect2, varscan2
- GRIK3 | c.2709C>T p.P903= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as rs191042265, COSV66141689; called by muse, mutect2, varscan2
